CCDI case PBCPJA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/991be7b9-9975-4b3d-81c7-c34c0507ac24

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.2 years (6,276 days).

Biospecimens (2 samples)
- Sample 0DWVEI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWVFH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
